Somatic mutation profile of tumor specimen MP2PRT-PAWAEZ-TMP1-A (aliquot MP2PRT-PAWAEZ-TMP1-A-1-0-D-A821-36) from MP2PRT case MP2PRT-PAWAEZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.7 years (4,264 days).
Specimen MP2PRT-PAWAEZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 199b11cb-ace5-43fe-9b8b-c15ec3982788.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAWAEZ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAWAEZ-NB1-A-1-0-D-A821-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8225111a-8194-4c73-9257-0a526b58b0eb

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 10, Silent 4, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FRMPD4 | c.2569G>A p.A857T | Missense Mutation (SNP) | VAF 181/323 reads (56%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs368784263; called by muse, mutect2, varscan2
- MAP2 | c.812C>T p.T271M | Missense Mutation (SNP) | VAF 209/480 reads (44%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as rs547929820, COSV52281438, COSV52293636; called by muse, mutect2, varscan2
- MKI67 | c.7868C>T p.T2623M | Missense Mutation (SNP) | VAF 60/446 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs368793936; called by muse, mutect2, varscan2
- PFKFB4 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 99/220 reads (45%) | PolyPhen benign (0.015); catalogued as rs776458096; called by muse, mutect2, varscan2
- TRIM50 | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 82/611 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.515); catalogued as rs370785473, COSV99392210; called by muse, mutect2, varscan2
- CHERP | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 314/768 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.026); called by muse, varscan2
- CPSF7 | c.1316G>A p.R439Q (on ENST00000394888 / NM_001136040.4; = p.R482Q on NM_024811.4) | Missense Mutation (SNP) | VAF 21/524 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.294); called by muse, mutect2
- IL12RB1 | c.8C>G p.P3R | Missense Mutation (SNP) | VAF 202/546 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MPP4 | c.1102G>T p.V368F | Missense Mutation (SNP) | VAF 97/265 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- NCKAP1 | c.1628+1G>A p.X543_splice | Splice Site (SNP) | VAF 33/73 reads (45%) | called by muse, mutect2, varscan2
- SPOP | c.385_386insCGCGGCAA p.K129Tfs*36 | Frame Shift Ins (INS) | VAF 124/355 reads (35%) | called by mutect2, pindel*, varscan2*
- TRPC7 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 130/547 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CLDN24 | c.432G>A p.T144= | Silent (SNP) | VAF 243/600 reads (41%) | catalogued as rs974162223; called by muse, mutect2, varscan2
- MYF6 | c.468G>A p.K156= | Silent (SNP) | VAF 133/374 reads (36%) | catalogued as COSV57352601, COSV57353668; called by muse, mutect2, varscan2
- PTPN23 | c.4083C>T p.P1361= | Silent (SNP) | VAF 141/393 reads (36%) | catalogued as rs200311135; called by muse, mutect2, varscan2
- TMTC3 | c.1905C>T p.F635= | Silent (SNP) | VAF 15/75 reads (20%) | called by muse, mutect2, varscan2
